TCGA case TCGA-WK-A8XX — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Brigham and Women's Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/04d45a95-4282-42e7-8e2f-2b7a5082e1b5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 1,164 days (3.2 years).

Diagnoses (6)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 70.4 years (25,701 days); Year of diagnosis: 2007; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Contiguous organ invaded: Kidney; Sites of involvement: Renal Vein / Lung, NOS / Kidney, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 7.
   Pathology details: Measurement type: Radiologic; Tumor burden: 5.5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 7.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 70.7 years (25,812 days); Days to diagnosis: 111 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
3. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Retroperitoneum. Age at diagnosis: 70.7 years (25,812 days); Days to diagnosis: 111 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 71.8 years (26,212 days); Days to diagnosis: 511 days (1.4 years); Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Bone, NOS. Age at diagnosis: 71.8 years (26,212 days); Days to diagnosis: 511 days (1.4 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Brain, NOS. Age at diagnosis: 73.4 years (26,821 days); Days to diagnosis: 1,120 days (3.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 111 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 111 days.
- Day 111 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 111 days.
- Day 511 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 511 days (1.4 years).
- Day 511 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 511 days (1.4 years).
- Day 1,120 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 1,120 days (3.1 years).
- Days to follow up: 1,164 days (3.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 22.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WK-A8XX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-WK-A8XX-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WK-A8XX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WK-A8XX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: Renal vein; Site of primary tumor other: Renal vein; Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Tumor burden pathologic: 7.0; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: Yes; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum; Submitted tumor site: Retroperitoneum/Upper abdominal - Other (please specify.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 7.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,164 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,164 days; disease-free interval: event (new tumor event after initially disease-free), 111 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 111 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WK-A8XX-01A-11D-A37B-01): tumor purity 0.75, ploidy 3.42, whole-genome doublings 1.
